Somatic mutation profile of tumor specimen TCGA-BA-6869-01A (aliquot TCGA-BA-6869-01A-11D-1870-08) from TCGA case TCGA-BA-6869, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.3 years (22,765 days).
Specimen TCGA-BA-6869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81eeb770-676f-4117-9e57-a249ed34fd57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-6869-10A (Blood Derived Normal), aliquot TCGA-BA-6869-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d0da8de-5a64-4231-b2b8-f11a3a3bdb25

The open-access MAF lists 527 somatic variants for this specimen: 395 protein-altering or splice-affecting, 117 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 117, Nonsense Mutation 29, Splice Site 10, Frame Shift Del 8, RNA 6, Intron 5, Frame Shift Ins 5, Splice Region 3, 3'UTR 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AARD | c.325-1G>A p.X109_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100991842; called by muse, mutect2, varscan2
- ABCA13 | c.7612A>T p.T2538S | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs1469819467, COSV101446867; called by muse, mutect2, varscan2
- ABCA6 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV99446058; called by muse, mutect2, varscan2
- ACKR2 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99825402; called by muse, mutect2, varscan2
- ACSBG1 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV99357145; called by muse, mutect2, varscan2
- ACTR5 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54762216; called by muse, mutect2, varscan2
- ADAM11 | c.1169-1G>T p.X390_splice | Splice Site (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99567220; called by muse, mutect2, varscan2
- ADAM8 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291630; called by muse, mutect2, varscan2
- ADAMTS12 | c.4469G>T p.G1490V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710460, COSV61283044; called by muse, mutect2, varscan2
- ADCY1 | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99811521; called by mutect2, varscan2
- ADGRB3 | c.1521C>A p.C507* | Nonsense Mutation (SNP) | VAF 42/75 reads (56%) | catalogued as COSV65422223; called by muse, mutect2, varscan2
- ADGRL2 | c.1540A>G p.K514E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.411); catalogued as COSV99587676; called by muse, mutect2, varscan2
- ADSS1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV100272159, COSV58272311; called by muse, mutect2
- AGBL1 | c.569G>C p.S190T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV101407941; called by muse, mutect2, varscan2
- AGPS | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51560637, COSV51563645; called by muse, mutect2, varscan2
- AHNAK2 | c.10547T>G p.L3516R | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100316343; called by muse, mutect2, varscan2
- AMER1 | c.2874G>T p.W958C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs780015689, COSV100365578; called by muse, varscan2
- ANK2 | c.2437C>A p.L813M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777436992, COSV100000376; called by muse, mutect2, varscan2
- ANK3 | c.12014G>A p.G4005D | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.984); catalogued as COSV99778893; called by muse, mutect2, varscan2
- ANKRD11 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV56371786, COSV99968638; called by muse, mutect2, varscan2
- ANO5 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61084823; called by muse, mutect2, varscan2
- APC2 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99279267; called by muse, mutect2, varscan2
- APOB | c.8336A>T p.N2779I | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99264406; called by muse, mutect2, varscan2
- ARAP2 | c.4631C>G p.P1544R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1199177235, COSV100394283; called by muse, mutect2, varscan2
- ARHGAP21 | c.4038G>T p.E1346D | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.311); catalogued as COSV100255921; called by muse, mutect2, varscan2
- ARHGAP35 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV101350798, COSV101351188; called by muse, mutect2, varscan2
- ARHGEF15 | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100730010; called by muse, varscan2
- ARL4D | c.116A>T p.Y39F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100186391; called by muse, mutect2, varscan2
- ART4 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99966849; called by muse, mutect2, varscan2
- ASIC2 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as COSV100726063, COSV100726672; called by muse, mutect2, varscan2
- ASPM | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99659837; called by muse, mutect2, varscan2
- AVPR1B | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899336; called by muse, mutect2, varscan2
- BCORL1 | c.4685G>T p.S1562I | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99498846; called by muse, mutect2, varscan2
- BPI | c.814C>T p.P272S (on ENST00000262865; = p.P268S on NM_001725.3) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99480462; called by muse, mutect2, varscan2
- BRCA2 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1064795525, CD021790, COSV101204018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK1 | c.2054G>A p.G685D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV100473765; called by muse, mutect2, varscan2
- BRWD3 | c.4891A>T p.T1631S | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); catalogued as COSV100955804; called by muse, mutect2, varscan2
- C20orf27 | c.337G>C p.E113Q (on ENST00000379772 / NM_001258429.2; = p.E138Q on NM_001039140.3) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99422037; called by muse, mutect2, varscan2
- C6 | c.1683C>A p.S561= | Splice Region (SNP) | VAF 55/153 reads (36%) | catalogued as COSV99666745; called by muse, mutect2, varscan2
- CAMTA1 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.396); catalogued as COSV100347351; called by muse, mutect2, varscan2
- CARD16 | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774893648, COSV100995085; called by muse, mutect2, varscan2
- CARD6 | c.332G>C p.S111T | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV99620470; called by muse, mutect2, varscan2
- CASD1 | c.2056A>G p.R686G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99802407; called by muse, mutect2, varscan2
- CCDC39 | c.808del p.E270Kfs*22 | Frame Shift Del (DEL) | VAF 47/81 reads (58%) | catalogued as COSV99866845; called by mutect2, pindel, varscan2
- CCM2L | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52950537, COSV99395021; called by muse, mutect2, varscan2
- CDH11 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 80/196 reads (41%) | catalogued as COSV99217586; called by muse, mutect2, varscan2
- CDH19 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs755899214, COSV100051163; called by muse, mutect2, varscan2
- CDH8 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100180206, COSV54867911; called by muse, mutect2, varscan2
- CEP164 | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV99632759; called by muse, mutect2, varscan2
- CEP170 | c.4696A>G p.I1566V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.919); catalogued as rs1558346921, COSV100316676; called by muse, mutect2, varscan2
- CFTR | c.3704G>T p.S1235I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as COSV99134600; called by muse, mutect2, varscan2
- CLCA1 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as COSV52324930; called by muse, mutect2, varscan2
- CLCNKB | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.465); catalogued as COSV100990210; called by muse, mutect2, varscan2
- CLEC14A | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs375051083, COSV100643515, COSV100643637; called by muse, mutect2, varscan2
- CLN3 | c.827A>T p.Q276L (on ENST00000360019 / NM_001286104.2; = p.Q300L on NM_000086.2) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100343150; called by muse, mutect2, varscan2
- CLSTN2 | c.895A>T p.T299S | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101515594; called by muse, mutect2, varscan2
- CNDP1 | c.1250C>G p.P417R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722249, COSV62595239; called by muse, mutect2, varscan2
- CNGB1 | c.3133A>T p.N1045Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99202164; called by muse, mutect2, varscan2
- CNTN5 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV99674417; called by muse, mutect2, varscan2
- CNTN5 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99674420; called by muse, mutect2, varscan2
- COL15A1 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV100897305, COSV100897519; called by muse, mutect2
- COL6A3 | c.4595C>A p.A1532E | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99796707; called by muse, mutect2, varscan2
- CR2 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889535, COSV100889550; called by muse, mutect2, varscan2
- CRHR2 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV100529804; called by muse, mutect2, varscan2
- CRYBB1 | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762942964, COSV99315890; called by muse, mutect2, varscan2
- CSMD1 | c.9285C>A p.A3095= (on ENST00000520002; = p.A3094= on NM_033225.6) | Splice Region (SNP) | VAF 56/171 reads (33%) | catalogued as COSV100145298; called by muse, varscan2
- CSMD3 | c.9932C>A p.S3311* (on ENST00000297405 / NM_001363185.1; = p.S3142* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV52240336, COSV99828362; called by muse, mutect2, varscan2
- CSMD3 | c.2971C>A p.R991S (on ENST00000297405 / NM_001363185.1; = p.R887S on NM_052900.3) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52182083, COSV52326902, COSV99828366; called by muse, mutect2, varscan2
- CUBN | c.10633G>C p.A3545P | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.765); catalogued as rs758001862, COSV100912271; called by muse, mutect2, varscan2
- CUBN | c.9208G>T p.V3070F | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100912272; called by muse, mutect2, varscan2
- CUL3 | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52366698; called by muse, mutect2, varscan2
- CUL9 | c.3802A>G p.N1268D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99335046; called by muse, mutect2, varscan2
- CYP2C8 | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100987898; called by muse, mutect2, varscan2
- CYP46A1 | c.449T>A p.L150* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99952507; called by muse, mutect2, varscan2
- DAAM2 | c.2392A>T p.M798L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99224939; called by muse, mutect2, varscan2
- DCC | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.295); catalogued as COSV100498786; called by muse, mutect2
- DDHD2 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV101240549, COSV68158217; called by muse, mutect2, varscan2
- DENND2A | c.928T>G p.S310A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV52056161; called by muse, mutect2, varscan2
- DENND4A | c.1876A>T p.I626F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101475283; called by muse, mutect2, varscan2
- DGKB | c.973C>A p.H325N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV99337487; called by muse, mutect2, varscan2
- DGKK | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101052925; called by muse, mutect2, varscan2
- DLC1 | c.2116G>A p.E706K (on ENST00000276297 / NM_001348081.2; = p.E269K on NM_006094.5) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.118); catalogued as rs1439867473, COSV99361898; called by muse, mutect2, varscan2
- DLGAP1 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 169/370 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV100228733, COSV99044153; called by muse, varscan2
- DLGAP1 | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 58/339 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs371186913; called by muse, varscan2
- DMD | c.3890G>C p.G1297A | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100818661; called by muse, mutect2, varscan2
- DNAH2 | c.12159G>T p.W4053C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101208985, COSV101209095; called by muse, mutect2, varscan2
- DNAH7 | c.10637G>A p.G3546D | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414352; called by muse, mutect2, varscan2
- DNAH7 | c.10636G>T p.G3546C | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1286638987, COSV56751615; called by muse, varscan2
- DNAH7 | c.9853T>G p.C3285G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100414357; called by muse, mutect2, varscan2
- DNAH8 | c.11087C>A p.T3696K | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100543923, COSV59451066; called by muse, mutect2, varscan2
- DNAH9 | c.9754C>A p.P3252T | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99304822; called by muse, mutect2, varscan2
- DNHD1 | c.12599C>G p.T4200S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.198); catalogued as COSV99599653; called by muse, mutect2, varscan2
- DOK7 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV100403211; called by muse, mutect2, varscan2
- DPP6 | c.2459C>G p.P820R (on ENST00000377770 / NM_001364500.2; = p.P758R on NM_001936.5) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123882, COSV100128246; called by muse, mutect2, varscan2
- DPPA4 | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as COSV100169285; called by muse, mutect2, varscan2
- DRD2 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100669395; called by muse, mutect2, varscan2
- DSCAM | c.3440A>T p.Q1147L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV101259496; called by muse, mutect2, varscan2
- DYNC2I1 | c.2369A>T p.E790V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101337625; called by muse, mutect2, varscan2
- DYSF | c.4226G>T p.R1409L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs758688467, COSV50269245, COSV99245257; called by muse, mutect2, varscan2
- EN2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV99818568; called by muse, mutect2, varscan2
- ENPEP | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV99487276; called by muse, mutect2
- ENPP3 | c.1585C>A p.P529T | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100716911; called by muse, mutect2, varscan2
- ERICH3 | c.630G>T p.R210S | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV58598724, COSV58601028; called by muse, mutect2, varscan2
- ETNPPL | c.609T>A p.S203R | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99625061; called by muse, mutect2, varscan2
- EVI5 | c.697-1G>T p.X233_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100789669; called by muse, mutect2, varscan2
- EXOC3L2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99374473; called by muse, mutect2, varscan2
- EXOC4 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99552872; called by muse, mutect2, varscan2
- EYA1 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100378904; called by muse, mutect2, varscan2
- EYA1 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs749811991, COSV100378906, COSV58158809; called by muse, mutect2, varscan2
- F13B | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.622); catalogued as COSV100803229; called by muse, mutect2, varscan2
- FAM118B | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100796844; called by muse, mutect2, varscan2
- FAM214B | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV100521229; called by muse, mutect2, varscan2
- FAR1 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1345591334, COSV100701520; called by muse, mutect2, varscan2
- FAT3 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV53101384, COSV99963353; called by muse, mutect2, varscan2
- FBN2 | c.8699G>T p.G2900V | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV52511023, COSV99325792; called by muse, mutect2, varscan2
- FBN2 | c.2266T>A p.C756S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99325794; called by muse, mutect2, varscan2
- FCGR3B | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376361357; called by muse, mutect2, varscan2
- FCHO1 | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs760083911, COSV53186026, COSV99405902; called by muse, mutect2, varscan2
- FER1L6 | c.198-1G>A p.X66_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101205590, COSV67552110; called by muse, mutect2, varscan2
- FIGN | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100291917, COSV60764866; called by muse, mutect2, varscan2
- FLG | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 148/425 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs1301326707, COSV100911148; called by muse, mutect2, varscan2
- FMN2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs754768476, COSV60433685, COSV60451990; called by muse, mutect2, varscan2
- FMN2 | c.4944A>T p.K1648N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100143838; called by muse, mutect2, varscan2
- FREM2 | c.5519G>T p.R1840L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV99747540; called by muse, mutect2, varscan2
- FREM2 | c.6697G>C p.G2233R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs958940440, COSV99747547; called by muse, mutect2, varscan2
- FZD4 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101536033; called by muse, mutect2, varscan2
- FZD5 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99776293; called by muse, mutect2, varscan2
- GABRA5 | c.555C>G p.H185Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV100164876; called by muse, mutect2, varscan2
- GAS7 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101450047, COSV101450091; called by muse, mutect2, varscan2
- GC | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV56740095, COSV99909514; called by muse, mutect2, varscan2
- GDPD4 | c.1472G>T p.W491L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100265133; called by muse, mutect2
- GLRA2 | c.818G>C p.W273S | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99490523; called by muse, mutect2, varscan2
- GNAI3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766607222, COSV63984496; called by muse, mutect2, varscan2
- GPATCH8 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 55/188 reads (29%) | catalogued as COSV100132524; called by muse, mutect2, varscan2
- GPLD1 | c.452A>T p.H151L | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100015144; called by muse, mutect2, varscan2
- GPR101 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs747441125, COSV99981303; called by muse, mutect2, varscan2
- GPR158 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 95/165 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753599474, COSV66286385; called by muse, mutect2, varscan2
- GPR63 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV100013201; called by muse, mutect2, varscan2
- GPRC6A | c.905G>T p.S302I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59951584; called by muse, mutect2, varscan2
- GRID1 | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.837); catalogued as COSV100022653, COSV60060238; called by muse, mutect2, varscan2
- GRM5 | c.2726G>T p.S909I | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100550843; called by muse, mutect2, varscan2
- GTF2I | c.369C>G p.C123W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259528; called by muse, mutect2, varscan2
- GTF2I | c.1279G>T p.E427* (on ENST00000573035 / NM_032999.4; = p.E386* on NM_001518.5) | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100259531; called by muse, mutect2, varscan2
- GTSE1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1393426138, COSV101483195; called by muse, mutect2, varscan2
- GUCY1A1 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.09); catalogued as COSV99637379; called by muse, mutect2, varscan2
- HAS1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as COSV99708272; called by muse, mutect2
- HBG2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as rs781082967, COSV100400587; called by muse, mutect2, varscan2
- HECTD4 | c.5516C>T p.P1839L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66388045, COSV66394913; called by muse, mutect2, varscan2
- HECW2 | c.3788G>T p.R1263I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53650225, COSV99646306; called by muse, mutect2, varscan2
- HMGCLL1 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99231656; called by muse, mutect2
- HMGCS1 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as rs372815381; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2055A>T p.R685S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV99647008; called by muse, mutect2, varscan2
- IGHG1 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs1448656902; called by muse, mutect2, varscan2
- IGHV4-59 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); catalogued as rs547611987; called by muse, mutect2, varscan2
- IL16 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100267212; called by muse, mutect2, varscan2
- IL1R1 | c.736T>A p.L246M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.951); catalogued as COSV99292458; called by muse, mutect2, varscan2
- IL24 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99686399; called by muse, mutect2, varscan2
- INSC | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV101088884; called by muse, varscan2
- INSC | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65410335; called by muse, mutect2, varscan2
- IQCD | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV100232300; called by muse, mutect2, varscan2
- IQCH | c.2508G>T p.V836= | Splice Region (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100245542; called by muse, mutect2, varscan2
- IRX1 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100116333; called by muse, mutect2, varscan2
- IRX1 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100116336, COSV57362387; called by muse, mutect2, varscan2
- ITFG1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV57747859; called by muse, mutect2, varscan2
- ITPRID1 | c.2129C>T p.T710I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100085916; called by muse, mutect2, varscan2
- KASH5 | c.760C>G p.Q254E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101483409; called by muse, mutect2, varscan2
- KCND2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100474411; called by muse, mutect2, varscan2
- KCNQ3 | c.1247T>A p.L416Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101195778; called by muse, mutect2, varscan2
- KCNU1 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs763915966, COSV67753864, COSV67753916; called by muse, mutect2, varscan2
- KDR | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55771595, COSV55777577, COSV99817002; called by muse, mutect2, varscan2
- KIAA2013 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927117; called by muse, mutect2, varscan2
- KIR3DL2 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 121/363 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV54389697, COSV99551857; called by muse, mutect2, varscan2
- KIT | c.1457A>T p.N486I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99853591; called by muse, mutect2, varscan2
- KLRB1 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs767621944, COSV99987194, COSV99987378; called by muse, mutect2, varscan2
- KRTAP6-2 | c.110G>C p.C37S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | PolyPhen benign (0.006); catalogued as rs771574598, COSV100588901; called by muse, mutect2, varscan2
- LATS1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.88); catalogued as COSV99485495; called by muse, mutect2, varscan2
- LDHC | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772362; called by muse, mutect2, varscan2
- LGI4 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs1425055786, COSV100032345; called by muse, mutect2, varscan2
- LINGO4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs774214528, COSV59092159; called by muse, mutect2, varscan2
- LMNB1 | c.964C>G p.Q322E | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99745704; called by muse, mutect2, varscan2
- LRP1B | c.12123G>T p.M4041I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101254176; called by muse, mutect2, varscan2
- LRP1B | c.11692A>T p.I3898F | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV101254177; called by muse, mutect2, varscan2
- LRP1B | c.10028G>C p.G3343A | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101254178; called by muse, mutect2, varscan2
- LRPAP1 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | catalogued as COSV99578834; called by muse, mutect2, varscan2
- LRRC7 | c.540G>T p.Q180H (on ENST00000651989 / NM_001370785.2; = p.Q147H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV99225323; called by muse, mutect2, varscan2
- LRRTM3 | c.1317C>G p.Y439* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as COSV100791536; called by muse, mutect2, varscan2
- LYZL4 | c.307A>G p.N103D | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs897886969, COSV99821171; called by muse, mutect2, varscan2
- MAGEC1 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.869); catalogued as COSV53573608, COSV53580961; called by muse, mutect2, varscan2
- MAP1A | c.7378T>A p.S2460T | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100288290; called by muse, mutect2, varscan2
- MAP1B | c.3814C>A p.L1272M | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.483); catalogued as COSV57098779, COSV99701992; called by muse, mutect2, varscan2
- MAP3K13 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 84/122 reads (69%) | catalogued as COSV99406652; called by muse, mutect2, varscan2
- MAPK8IP1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs771163572, COSV99571221; called by muse, mutect2
- MAPT | c.1662G>C p.Q554H (on ENST00000262410 / NM_001377265.1; = p.Q162H on NM_005910.5) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV99290052; called by muse, mutect2, varscan2
- MBD1 | c.110+1G>A p.X37_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as rs765681778, COSV99495764; called by muse, mutect2, varscan2
- MECOM | c.842A>G p.Y281C (on ENST00000468789 / NM_001105078.4; = p.Y469C on NM_004991.4) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs972600027, COSV99244320; called by muse, varscan2
- MEF2C | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100426285, COSV60931954; called by muse, mutect2, varscan2
- MEF2C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100424946; called by muse, mutect2, varscan2
- METTL22 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99371577; called by muse, mutect2, varscan2
- MGAM | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs781964893, COSV101527414; called by muse, mutect2, varscan2
- MIGA1 | c.1546A>T p.K516* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as COSV100889751; called by muse, mutect2, varscan2
- MKI67 | c.8393A>G p.E2798G | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100896321; called by muse, mutect2
- MME | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 45/57 reads (79%) | catalogued as COSV100852299; called by muse, mutect2, varscan2
- MMP10 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99666458; called by muse, mutect2, varscan2
- MRO | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs143359256, COSV99839063; called by muse, mutect2, varscan2
- MS4A4A | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100557704; called by muse, mutect2, varscan2
- MSANTD3-TMEFF1 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV100614490; called by muse, mutect2, varscan2
- MUC16 | c.17439G>C p.E5813D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV101198801; called by muse, mutect2, varscan2
- MYO16 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV51822910, COSV99193690, COSV99194024; called by muse, mutect2, varscan2
- MYO5C | c.2578G>T p.V860L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99954307; called by muse, mutect2, varscan2
- NAA11 | c.15C>G p.N5K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV54515210; called by muse, mutect2
- NEB | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99417407; called by muse, mutect2, varscan2
- NELL2 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.179); catalogued as COSV100419025; called by muse, mutect2, varscan2
- NFAT5 | c.3326C>G p.S1109C | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV100590606; called by muse, mutect2, varscan2
- NHS | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | catalogued as COSV101196462; called by muse, mutect2, varscan2
- NME8 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs981266761, COSV52254446, COSV99552967; called by muse, mutect2, varscan2
- NPSR1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); catalogued as rs377675594; called by muse, mutect2, varscan2
- NPY1R | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99648580; called by muse, mutect2, varscan2
- NR2F2 | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101240963; called by muse, mutect2, varscan2
- NRAP | c.4778T>C p.F1593S (on ENST00000359988 / NM_001322945.2; = p.F1558S on NM_006175.4) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as COSV100667869; called by muse, mutect2, varscan2
- NSA2 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99713613; called by muse, mutect2, varscan2
- NSD1 | c.2120C>G p.S707* | Nonsense Mutation (SNP) | VAF 45/71 reads (63%) | catalogued as COSV100728593; called by muse, mutect2, varscan2
- NT5DC3 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230904, COSV67321315; called by muse, mutect2, varscan2
- NUTM1 | c.659A>T p.Y220F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.788); catalogued as COSV100412153; called by muse, mutect2, varscan2
- NXF3 | c.1475T>A p.L492H | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67703054; called by muse, mutect2, varscan2
- OPCML | c.609C>G p.S203R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.249); catalogued as COSV100098884, COSV59417502, COSV59451112; called by muse, mutect2, varscan2
- OR10G4 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100304744, COSV100304816; called by muse, mutect2, varscan2
- OR10T2 | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.897); catalogued as COSV100554873; called by muse, mutect2, varscan2
- OR11A1 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101010689; called by muse, mutect2, varscan2
- OR11L1 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV63314778; called by muse, mutect2, varscan2
- OR11L1 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs767711381, COSV100869396; called by muse, mutect2, varscan2
- OR1L1 | c.688G>T p.D230Y (on ENST00000373686; = p.D180Y on NM_001005236.3) | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100542103; called by muse, mutect2, varscan2
- OR2T11 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100424719, COSV58185532; called by muse, mutect2, varscan2
- OR2T27 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100788147; called by muse, mutect2, varscan2
- OR3A1 | c.467T>C p.F156S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV100041596; called by muse, mutect2, varscan2
- OR51B6 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100970888; called by muse, mutect2, varscan2
- OR52I2 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763803996, COSV100442860; called by muse, mutect2, varscan2
- OR5F1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs751091302; called by muse, mutect2
- OR5F1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780899733, COSV53547432, COSV99558435; called by muse, mutect2
- OR5M3 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs777165702, COSV100392379; called by muse, mutect2, varscan2
- OR5M8 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100510579, COSV100510613; called by muse, mutect2, varscan2
- OR6A2 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1564904739, COSV100215640; called by muse, mutect2, varscan2
- OR8D2 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100658866; called by muse, mutect2, varscan2
- OR8U1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.167); catalogued as COSV100163798; called by muse, mutect2, varscan2
- OR9A2 | c.359T>A p.V120E | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100628185; called by muse, mutect2, varscan2
- P3H3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99300986; called by muse, mutect2, varscan2
- PABPC5 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100442189; called by muse, mutect2, varscan2
- PAPPA2 | c.903C>A p.N301K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100866628; called by muse, mutect2
- PCDH11X | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159832296, COSV100009614; called by muse, mutect2, varscan2
- PCDH18 | c.537T>A p.N179K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100787120; called by muse, mutect2, varscan2
- PCDHA10 | c.986T>C p.M329T | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs374158544; called by muse, mutect2, varscan2
- PCDHA10 | c.1592A>T p.Q531L | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs1554150415, COSV100248738; called by muse, mutect2, varscan2
- PCDHA6 | c.2035T>A p.S679T | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV100971272, COSV100971307; called by muse, mutect2, varscan2
- PCDHB7 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50788951; called by muse, mutect2, varscan2
- PCDHGA7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV99533574; called by muse, mutect2, varscan2
- PCLO | c.13359G>T p.L4453F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.935); catalogued as COSV61633988, COSV61664110; called by muse, mutect2, varscan2
- PDE1C | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.717); catalogued as COSV101275457, COSV68819282; called by muse, mutect2, varscan2
- PDGFRA | c.2960C>A p.A987E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as COSV99955922; called by muse, mutect2, varscan2
- PEX11A | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV100261455, COSV55585386; called by muse, mutect2, varscan2
- PHOX2B | c.317C>G p.T106S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV56928506, COSV99890965; called by muse, mutect2, varscan2
- PHRF1 | c.3275G>T p.R1092L (on ENST00000264555 / NM_001286581.2; = p.R1091L on NM_020901.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs1199430082, COSV52752310; called by muse, mutect2, varscan2
- PHTF2 | c.1531G>A p.G511S (on ENST00000248550 / NM_001366089.1; = p.G473S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as rs752290529, COSV99301273; called by muse, mutect2, varscan2
- PIK3R6 | c.2030A>G p.Q677R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs760709443, COSV100266273; called by muse, mutect2, varscan2
- PKD1L1 | c.4800G>C p.Q1600H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV99218938; called by muse, mutect2, varscan2
- PLCE1 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99594024; called by muse, mutect2, varscan2
- PLCL2 | c.2090G>C p.C697S (on ENST00000615277 / NM_001144382.2; = p.C571S on NM_015184.5) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101196612; called by muse, mutect2, varscan2
- PLEKHG3 | c.2014G>C p.E672Q (on ENST00000394691; = p.E728Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55982474, COSV99906385; called by muse, mutect2, varscan2
- PLEKHH3 | c.1444T>A p.L482M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.211); catalogued as rs1237055702, COSV99257376; called by muse, mutect2, varscan2
- PLXNA3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.574); catalogued as COSV63754606; called by muse, mutect2, varscan2
- PNLIPRP2 | c.419T>A p.I140N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100077661; called by muse, mutect2, varscan2
- PPFIBP1 | c.2803G>C p.G935R (on ENST00000318304 / NM_177444.3; = p.G929R on NM_003622.4) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV99944504; called by muse, mutect2, varscan2
- PPP2R2B | c.704G>C p.C235S (on ENST00000394409; = p.C301S on NM_181674.2) | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV100353847; called by muse, mutect2, varscan2
- PRAMEF1 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV100179564; called by muse, mutect2, varscan2
- PRAMEF4 | c.1287C>A p.C429* | Nonsense Mutation (SNP) | VAF 115/320 reads (36%) | catalogued as COSV99339603; called by muse, mutect2, varscan2
- PRDM1 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100958644; called by muse, mutect2, varscan2
- PRKD1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as COSV100119543; called by muse, mutect2, varscan2
- PRPF8 | c.3507G>T p.Q1169H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100517259; called by muse, mutect2, varscan2
- PRPS1L1 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101552920; called by muse, mutect2, varscan2
- PRSS36 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99191238; called by muse, mutect2
- PTPRC | c.1603A>G p.K535E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs780306635, COSV100722272; called by muse, mutect2, varscan2
- PTPRH | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs771653849, COSV99670823; called by muse, mutect2, varscan2
- PUS7 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 59/151 reads (39%) | catalogued as COSV100708473; called by muse, mutect2, varscan2
- PXDN | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99412694; called by muse, mutect2, varscan2
- RECQL | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV101388865; called by muse, mutect2, varscan2
- REG3G | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as COSV55450508, COSV99709298; called by muse, mutect2, varscan2
- RET | c.1753T>A p.C585S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100392812; called by muse, mutect2, varscan2
- RIMS2 | c.1648G>C p.D550H (on ENST00000666250 / NM_001348490.2; = p.D358H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99164004; called by muse, mutect2, varscan2
- RNF182 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.076); catalogued as COSV101337839, COSV101337855; called by muse, mutect2, varscan2
- RNF214 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV100326559; called by muse, mutect2
- ROBO2 | c.3065del p.S1022Tfs*9 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as COSV59942511; called by mutect2, pindel, varscan2
- RYR1 | c.2148T>A p.D716E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615028; called by muse, mutect2, varscan2
- SASH1 | c.3359G>T p.C1120F | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100821010; called by muse, mutect2, varscan2
- SCN1A | c.4745T>C p.V1582A (on ENST00000303395 / NM_001202435.3; = p.V1571A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV100319697; called by muse, mutect2, varscan2
- SCN9A | c.4897C>A p.L1633M (on ENST00000303354; = p.L1622M on NM_002977.3) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100311929; called by muse, mutect2, varscan2
- SEC31B | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100947255; called by muse, mutect2, varscan2
- SEMA5A | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV101227427; called by muse, mutect2, varscan2
- SEPHS2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101529308; called by muse, mutect2, varscan2
- SETBP1 | c.2894A>G p.Q965R | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99952461; called by muse, mutect2, varscan2
- SI | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV100014518; called by muse, mutect2, varscan2
- SI | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100014520, COSV52293595; called by muse, mutect2, varscan2
- SLC12A4 | c.1983G>A p.W661* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99862895; called by muse, mutect2, varscan2
- SLC17A1 | c.34+1G>A p.X12_splice | Splice Site (SNP) | VAF 74/155 reads (48%) | catalogued as COSV55077753, COSV99765654; called by muse, mutect2, varscan2
- SLC19A3 | c.521T>A p.V174D | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99295726; called by muse, mutect2, varscan2
- SLC22A2 | c.956A>C p.Q319P | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV100870954; called by muse, mutect2, varscan2
- SLC39A10 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV100660552; called by muse, mutect2, varscan2
- SLC41A2 | c.403A>C p.I135L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99316274; called by muse, mutect2, varscan2
- SLCO1C1 | c.1186+2T>G p.X396_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56879505, COSV99858716; called by muse, mutect2, varscan2
- SLITRK3 | c.673A>T p.M225L | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs757666327, COSV99578748; called by muse, mutect2, varscan2
- SORL1 | c.4642G>A p.A1548T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as rs978479847, CM164124, COSV99493199; called by muse, mutect2
- SOX7 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as rs756585518, COSV100448989, COSV58731119; called by muse, mutect2, varscan2
- SPHKAP | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100763845; called by muse, mutect2, varscan2
- SPOCD1 | c.1424A>G p.Y475C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99929549; called by muse, mutect2, varscan2
- SRRM4 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV57411926, COSV99938015; called by muse, varscan2
- STAT5B | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510764; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2213A>G p.Q738R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); catalogued as COSV100561604; called by muse, mutect2, varscan2
- SUSD2 | c.2428C>A p.R810S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV100844228; called by muse, mutect2, varscan2
- SYNE1 | c.17050C>T p.P5684S (on ENST00000367255 / NM_182961.4; = p.P5613S on NM_033071.3) | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as COSV99556937; called by muse, mutect2, varscan2
- SYNJ1 | c.3292G>T p.G1098C | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100449089; called by muse, mutect2, varscan2
- TBX18 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.79); catalogued as rs1207416912, COSV100858464; called by muse, mutect2, varscan2
- TCAIM | c.1348G>C p.V450L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100703208; called by muse, mutect2, varscan2
- TECRL | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101168616, COSV67087739, COSV67087908; called by muse, mutect2, varscan2
- TEX13A | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100780900; called by muse, mutect2, varscan2
- TGM4 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs904430641, COSV99942195; called by muse, mutect2, varscan2
- THSD7B | c.3260C>A p.T1087K (on ENST00000272643; = p.T1085K on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV99746555; called by muse, mutect2, varscan2
- THUMPD2 | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99572044; called by muse, mutect2, varscan2
- TIE1 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV100992029; called by muse, mutect2, varscan2
- TMC3 | c.2800C>A p.R934S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV63923369, COSV63924852; called by muse, mutect2, varscan2
- TNS3 | c.3683A>G p.D1228G | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100235105; called by muse, mutect2, varscan2
- TNS3 | c.2011G>A p.G671R | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV100235108; called by muse, mutect2, varscan2
- TPD52 | c.140-1G>T p.X47_splice (on ENST00000379097 / NM_001025252.3; = p.X7_splice on NM_005079.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 41/127 reads (32%) | catalogued as COSV100990737; called by muse, mutect2, varscan2
- TPO | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV100220158; called by muse, mutect2, varscan2
- TRAV8-2 | c.287C>A p.T96K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1295307417; called by muse, mutect2, varscan2
- TRIM60 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV100593952; called by muse, mutect2, varscan2
- TRIM68 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.951); catalogued as COSV100331649; called by muse, mutect2, varscan2
- TRIP12 | c.4642C>T p.Q1548* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99389640; called by muse, mutect2, varscan2
- TRO | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV99436022; called by muse, mutect2, varscan2
- TRPA1 | c.2254A>T p.I752F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100083533; called by muse, mutect2, varscan2
- TRPC7 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397312641, COSV61454306; called by muse, mutect2, varscan2
- TTN | c.42926G>T p.G14309V (on ENST00000591111; = p.G6885V on NM_003319.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | PolyPhen probably damaging (1); catalogued as COSV100600561; called by muse, mutect2, varscan2
- TTN | c.26329A>T p.S8777C (on ENST00000591111; = p.S7850C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | PolyPhen possibly damaging (0.494); catalogued as COSV100600563; called by muse, mutect2, varscan2
- TUBA3C | c.1041C>A p.C347* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101313844; called by muse, mutect2, varscan2
- UBB | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs951628457, COSV100141598; called by muse, mutect2, varscan2
- UGT2B10 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99608010; called by muse, mutect2, varscan2
- UHRF1BP1L | c.339-2A>G p.X113_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99691275; called by muse, mutect2, varscan2
- UNC5D | c.145G>C p.A49P | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.147); catalogued as COSV99773295; called by muse, mutect2, varscan2
- USH2A | c.11932G>C p.A3978P | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as COSV100231279; called by muse, mutect2, varscan2
- USP19 | c.2429G>T p.R810L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025932; called by muse, mutect2, varscan2
- VEPH1 | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV100747441; called by muse, mutect2, varscan2
- VIP | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 76/123 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772117174, COSV100923919; called by muse, mutect2, varscan2
- VPS13B | c.4681A>T p.T1561S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100661204; called by muse, mutect2, varscan2
- VSTM4 | c.830T>G p.V277G | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV100251414, COSV60528871; called by muse, mutect2, varscan2
- WARS2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346097; called by muse, mutect2, varscan2
- WDR70 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54275971; called by muse, mutect2, varscan2
- WSCD2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54581632, COSV99774256; called by muse, mutect2, varscan2
- XDH | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV65148276, COSV65149250; called by muse, mutect2, varscan2
- XIRP2 | c.1173G>T p.W391C (on ENST00000628543; = p.W566C on NM_152381.6) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54693559, COSV99740085; called by muse, mutect2, varscan2
- ZBBX | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1202755644, COSV100283460; called by muse, mutect2, varscan2
- ZNF148 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 106/164 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100642021; called by muse, mutect2, varscan2
- ZNF208 | c.3251C>A p.P1084H | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1395480824, COSV101236900; called by muse, mutect2, varscan2
- ZNF256 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV56597912, COSV99990693; called by muse, mutect2, varscan2
- ZNF280B | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100840220, COSV99081441; called by muse, mutect2, varscan2
- ZNF324 | c.1287G>C p.Q429H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV99543167; called by muse, mutect2, varscan2
- ZNF430 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV99841649; called by muse, mutect2, varscan2
- ZNF443 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100041983; called by muse, mutect2, varscan2
- ZNF592 | c.409A>C p.T137P | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100245741; called by muse, mutect2, varscan2
- ZNF660 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs549519379, COSV59549750; called by muse, mutect2, varscan2
- ZNF831 | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV100925876, COSV64039643; called by muse, mutect2, varscan2
- ZPBP | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99249297; called by muse, mutect2, varscan2
- CDC20B | c.302_305del p.E101Vfs*6 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- FEZF2 | c.542C>G p.P181R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2
- FLRT3 | c.1459_1460insA p.L487Hfs*5 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | called by pindel, varscan2
- FRG2C | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- FRG2C | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- IGKV1D-42 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGKV3D-15 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGKV3D-20 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- INTS10 | c.696del p.S233Afs*9 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- KTN1 | c.3710T>G p.L1237W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC4 | c.70dup p.L24Pfs*31 | Frame Shift Ins (INS) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MUC2 | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEXMIF | c.2127dup p.K710* | Frame Shift Ins (INS) | VAF 33/66 reads (50%) | called by mutect2, pindel, varscan2
- PCDHB3 | c.662del p.P221Lfs*8 | Frame Shift Del (DEL) | VAF 37/76 reads (49%) | called by mutect2, pindel, varscan2
- PCNT | c.4892del p.G1631Afs*11 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.4400T>A p.F1467Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PKP2 | c.1825_1826del p.C609Hfs*4 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
- RP1 | c.424dup p.V142Gfs*87 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1690+1del p.X564_splice | Splice Site (DEL) | VAF 89/178 reads (50%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TADA2A | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TAS2R8 | c.197del p.G66Afs*3 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel, varscan2
- TRAV26-2 | c.118A>T p.N40Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TRBV2 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- UNC45B | c.1658dup p.A554Cfs*7 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- ABCA13 | c.1545C>A p.V515= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV101329962; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3738G>T p.G1246= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99717600; called by muse, mutect2, varscan2
- ADGRV1 | c.6759G>A p.K2253= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV67994912; called by muse, mutect2, varscan2
- ALOX12 | c.1764T>C p.C588= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99277943; called by muse, mutect2, varscan2
- ANKRD52 | c.1935C>T p.L645= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99921135; called by muse, mutect2
- ASTN2 | c.3699G>T p.L1233= (on ENST00000313400 / NM_001365069.1; = p.L1182= on NM_014010.5) | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV56003198, COSV99940429; called by muse, mutect2, varscan2
- ASXL3 | c.183C>T p.N61= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99323930; called by muse, mutect2
- ATP6V1C2 | c.1203G>A p.V401= (on ENST00000272238 / NM_001039362.2; = p.V355= on NM_144583.4) | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99694486, COSV99694956; called by muse, mutect2, varscan2
- ATRNL1 | c.2676G>T p.L892= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100369728; called by muse, varscan2
- BDP1 | c.2106A>G p.V702= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100702853; called by muse, mutect2, varscan2
- BTBD16 | c.45C>A p.V15= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV99584591; called by muse, mutect2, varscan2
- C1QL3 | c.333C>T p.N111= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs1408173067, COSV100126959; called by muse, mutect2
- C9 | c.1299C>G p.T433= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV99661853; called by muse, mutect2, varscan2
- CALHM1 | c.402C>T p.P134= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs772629749, COSV61708303; called by muse, mutect2, varscan2
- CC2D1B | c.501C>T p.H167= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs376425581; called by muse, mutect2, varscan2
- CCDC130 | c.444G>T p.R148= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99681161; called by muse, mutect2, varscan2
- CD163 | c.1677A>C p.V559= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100775742; called by muse, mutect2, varscan2
- CDH11 | c.1839C>T p.A613= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV51757730; called by muse, mutect2, varscan2
- CDK14 | c.537C>T p.I179= (on ENST00000380050 / NM_001287135.2; = p.I161= on NM_012395.3) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99724221; called by muse, mutect2, varscan2
- CLIC6 | c.1290G>C p.A430= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100659158; called by muse, mutect2, varscan2
- CNGA3 | c.405C>T p.P135= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1300746995, COSV99736316; called by muse, mutect2, varscan2
- CNKSR1 | c.1059C>T p.P353= (on ENST00000374253 / NM_001297647.2; = p.P346= on NM_006314.3) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100836707; called by muse, mutect2, varscan2
- CNRIP1 | c.465G>T p.L155= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99721143; called by muse, mutect2, varscan2
- CNTN5 | c.468C>A p.T156= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV99674415; called by muse, mutect2, varscan2
- COL6A6 | c.3405G>A p.V1135= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as COSV100650001; called by muse, mutect2, varscan2
- COQ5 | c.666C>G p.V222= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99942217; called by muse, mutect2, varscan2
- CRACD | c.3453A>G p.P1151= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs753314401, COSV99948855; called by muse, mutect2, varscan2
- CRACDL | c.1185C>A p.P395= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs766214701, COSV101194020; called by muse, varscan2
- CTTNBP2 | c.712C>A p.R238= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV50392601, COSV99353371; called by muse, mutect2, varscan2
- DDX60L | c.4083C>A p.S1361= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99487165; called by muse, mutect2, varscan2
- DIAPH3 | c.654G>A p.G218= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs776748682, COSV57366566, COSV99933035; called by muse, mutect2, varscan2
- DMBT1 | c.7323G>C p.T2441= (on ENST00000338354 / NM_001377530.1; = p.T1684= on NM_004406.3) | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100352467, COSV100354333; called by muse, mutect2, varscan2
- DNHD1 | c.12165C>T p.A4055= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99599652; called by muse, mutect2, varscan2
- DNM2 | c.819C>T p.G273= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1464745378, COSV100116965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP18 | c.60C>G p.L20= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100588819, COSV100588830, COSV100588857; called by muse, mutect2, varscan2
- DYRK1B | c.1056G>T p.G352= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100546484; called by muse, mutect2, varscan2
- ELANE | c.75G>A p.A25= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs202147367, COSV52256355; called by muse, mutect2, varscan2
- FAM135B | c.535T>C p.L179= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs745431814, COSV99356543; called by muse, mutect2, varscan2
- FAM47B | c.1275G>T p.P425= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as COSV100264156, COSV61455837; called by muse, mutect2, varscan2
- FAM53B | c.768G>T p.L256= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99784850; called by muse, mutect2, varscan2
- FAT3 | c.9654T>A p.S3218= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99963356; called by muse, mutect2, varscan2
- GAL3ST2 | c.168C>T p.F56= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99510785; called by muse, mutect2, varscan2
- GAS2L2 | c.837C>T p.H279= | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as rs782555608; called by muse, mutect2, varscan2
- GC | c.657C>G p.V219= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99909516; called by muse, mutect2, varscan2
- GGT5 | c.975G>C p.T325= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV54069876, COSV99571349; called by muse, mutect2, varscan2
- GNS | c.1053A>G p.P351= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs780928340, COSV99253671; called by muse, mutect2, varscan2
- GRM8 | c.2415C>A p.A805= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100281513; called by muse, mutect2, varscan2
- H1-5 | c.138G>A p.L46= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs374541448, COSV58899291; called by muse, mutect2, varscan2
- H3C4 | c.276G>T p.A92= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV100587122; called by muse, mutect2, varscan2
- HCN1 | c.2340C>G p.T780= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100299237, COSV57491654; called by muse, mutect2, varscan2
- HCN1 | c.1143C>A p.V381= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs761760627, COSV100299239, COSV100301749, COSV57540975; called by muse, mutect2, varscan2
- HECTD4 | c.4446C>G p.V1482= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100295908; called by muse, mutect2, varscan2
- IFIT5 | c.855G>A p.L285= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs372927340; called by muse, mutect2, varscan2
- IGHG1 | c.618C>T p.V206= | Silent (SNP) | VAF 61/261 reads (23%) | called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.69G>T p.L23= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- JADE1 | c.321C>T p.L107= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV99885500; called by muse, mutect2, varscan2
- KCNJ1 | c.756A>T p.V252= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV60661642, COSV60662773; called by muse, mutect2, varscan2
- KIF21A | c.3348A>G p.V1116= (on ENST00000361418 / NM_001378440.1; = p.V1103= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs191460813, COSV100735372; called by muse, mutect2, varscan2
- KIF21B | c.3714C>G p.P1238= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100144026; called by muse, mutect2, varscan2
- LRRK2 | c.4608G>C p.S1536= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100109546; called by muse, mutect2, varscan2
- LRRTM1 | c.981G>A p.S327= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1393641772, COSV54444513, COSV99702060; called by muse, mutect2, varscan2
- MAGEL2 | c.2091C>A p.P697= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100045753; called by muse, mutect2
- MATN1 | c.1377C>T p.A459= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101056222; called by muse, mutect2, varscan2
- MUC16 | c.12057C>T p.D4019= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs778816991, COSV67489689; called by muse, mutect2, varscan2
- NLGN2 | c.597A>T p.S199= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100259322; called by muse, mutect2, varscan2
- NRXN1 | c.462C>T p.F154= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1489077061, COSV68011574; called by muse, mutect2, varscan2
- NUAK1 | c.1113C>A p.S371= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs1298940190, COSV99776763; called by muse, mutect2, varscan2
- NUTM2G | c.519G>A p.G173= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as rs994662973, COSV100672629; called by muse, mutect2, varscan2
- OR4B1 | c.918A>T p.P306= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100535515; called by muse, mutect2, varscan2
- OR4D2 | c.528C>T p.N176= | Silent (SNP) | VAF 52/163 reads (32%) | catalogued as COSV73459790; called by muse, mutect2, varscan2
- OR5AR1 | c.717C>A p.S239= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV100265600; called by muse, mutect2, varscan2
- OR9I1 | c.396T>C p.Y132= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100109586; called by muse, mutect2, varscan2
- PAK5 | c.666C>A p.A222= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs267606070, COSV100781194, COSV100781252; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.42T>G p.P14= (on ENST00000259318 / NM_001136562.3; = p.P245= on NM_007203.5) | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV99394869; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.735G>T p.P245= (on ENST00000259318 / NM_001136562.3; = p.P476= on NM_007203.5) | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs775592313, COSV99394872; called by muse, mutect2, varscan2
- PCDHA12 | c.1282C>A p.R428= | Silent (SNP) | VAF 140/229 reads (61%) | catalogued as COSV100248744, COSV56475266; called by muse, mutect2, varscan2
- PCDHA4 | c.1353C>T p.N451= | Silent (SNP) | VAF 70/100 reads (70%) | catalogued as rs782636671, COSV63539191; called by muse, mutect2, varscan2
- PLEKHA7 | c.1998G>T p.L666= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100850149; called by muse, mutect2, varscan2
- POU5F2 | c.825G>A p.R275= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101232689; called by muse, mutect2, varscan2
- PPFIA2 | c.1221T>A p.P407= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV100332240; called by muse, mutect2, varscan2
- PPP1R9A | c.1515G>T p.V505= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99194597, COSV99194879; called by muse, mutect2, varscan2
- PRRX1 | c.54C>A p.R18= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99509420; called by muse, mutect2, varscan2
- PTPRO | c.1056C>G p.P352= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV55512808, COSV99840047; called by muse, mutect2, varscan2
- PXDNL | c.3621T>C p.P1207= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100682447; called by muse, mutect2, varscan2
- RASAL1 | c.1764C>T p.F588= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV99921535; called by muse, mutect2, varscan2
- RFPL1 | c.261G>A p.K87= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV100585671, COSV62977542; called by muse, mutect2, varscan2
- RIMS2 | c.1524C>T p.R508= (on ENST00000666250 / NM_001348490.2; = p.R316= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV51716870; called by muse, mutect2, varscan2
- RNF150 | c.318C>A p.T106= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100153090; called by muse, mutect2, varscan2
- RUSC2 | c.2868G>A p.L956= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100770643; called by muse, mutect2, varscan2
- SCN9A | c.4896G>C p.T1632= (on ENST00000303354; = p.T1621= on NM_002977.3) | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as COSV100311930; called by muse, mutect2, varscan2
- SEMA5B | c.417C>A p.I139= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99531130; called by muse, mutect2, varscan2
- SEPHS1 | c.324C>T p.L108= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100525713; called by muse, mutect2, varscan2
- SERGEF | c.831G>C p.L277= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs747491016, COSV99787013; called by muse, mutect2, varscan2
- SGMS1 | c.252C>T p.H84= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100693211; called by muse, mutect2, varscan2
- SLC14A1 | c.495T>C p.N165= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as rs1406159042, COSV100424901; called by muse, mutect2, varscan2
- SLC5A7 | c.1323T>A p.S441= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV99886364; called by muse, mutect2, varscan2
- SLIT1 | c.3306C>G p.V1102= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99820837; called by muse, mutect2, varscan2
- SMYD1 | c.1056G>C p.R352= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV101352407; called by muse, mutect2, varscan2
- SPATA31E1 | c.2637C>T p.A879= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100350094; called by muse, mutect2, varscan2
- SYNE1 | c.18084G>C p.L6028= (on ENST00000367255 / NM_182961.4; = p.L5957= on NM_033071.3) | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV99556907; called by muse, mutect2, varscan2
- TAF4 | c.1983A>G p.L661= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1181389582, COSV99433690; called by muse, mutect2, varscan2
- TAS2R60 | c.711C>A p.P237= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100223484, COSV60330743; called by muse, mutect2, varscan2
- TBC1D21 | c.666T>A p.A222= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100311232; called by muse, mutect2, varscan2
- TC2N | c.489C>T p.N163= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100562819; called by muse, mutect2, varscan2
- TLR4 | c.196C>T p.L66= (on ENST00000355622 / NM_138554.5; = p.L26= on NM_003266.4) | Silent (SNP) | VAF 56/199 reads (28%) | catalogued as COSV100790619, COSV62923311; called by muse, mutect2, varscan2
- TMPRSS11F | c.1290T>C p.D430= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs779572801, COSV100678296; called by muse, mutect2, varscan2
- TNIK | c.1884G>T p.V628= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV99455875; called by muse, mutect2, varscan2
- TNN | c.2766T>A p.A922= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99511380; called by muse, mutect2
- TRAV7 | c.312A>T p.S104= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- TRIM16L | c.981C>A p.I327= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101192589; called by muse, mutect2, varscan2
- UGT2B7 | c.1440C>A p.A480= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as COSV100535133; called by muse, mutect2, varscan2
- USH2A | c.8886T>A p.L2962= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100231280; called by muse, mutect2, varscan2
- ZFYVE26 | c.699G>T p.G233= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100720202; called by muse, mutect2, varscan2
- ZNF462 | c.4878A>G p.E1626= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99471126; called by muse, mutect2, varscan2
- ZNF512B | c.654C>T p.V218= | Silent (SNP) | VAF 74/256 reads (29%) | catalogued as rs373702537; called by muse, mutect2, varscan2
- ZNF518B | c.3141C>T p.D1047= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV100456609; called by muse, mutect2, varscan2
- ZNF676 | c.897C>T p.T299= (on ENST00000650058; = p.T267= on NM_001001411.3) | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs1379319403, COSV101236126, COSV68093012; called by muse, mutect2, varscan2
- ADAMTSL1 | c.-1C>A | 5'UTR (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99441558; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821885 G>A | 5'Flank (SNP) | VAF 11/17 reads (65%) | catalogued as rs1170509316; called by muse, mutect2, varscan2
- ATAD3B | c.*408G>A | 3'UTR (SNP) | VAF 23/40 reads (58%) | catalogued as rs757100078, COSV100426341; called by muse, mutect2, varscan2
- BTN2A3P | n.1578C>A | RNA (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- CD300LD | c.40+84T>A | Intron (SNP) | VAF 53/154 reads (34%) | catalogued as COSV100032338; called by muse, mutect2, varscan2
- FAM86C1P | n.362C>A | RNA (SNP) | VAF 51/183 reads (28%) | catalogued as rs564433101, COSV100660613; called by muse, varscan2
- KCNIP4 | c.62-421121G>T | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as COSV101184806; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421122G>C | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as COSV101184807; called by muse, mutect2, varscan2
- KNOP1P1 | n.166G>T | RNA (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- MIR1269A | n.48C>G | RNA (SNP) | VAF 28/76 reads (37%) | catalogued as rs747745340; called by muse, mutect2, varscan2
- PCDHA8 | c.2394+46T>C | Intron (SNP) | VAF 25/46 reads (54%) | catalogued as rs782681810, COSV100969219; called by muse, mutect2, varscan2
- SNORD114-26 | n.52G>C | RNA (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- SNORD115-10 | n.57G>T | RNA (SNP) | VAF 121/374 reads (32%) | called by muse, mutect2, varscan2
- TBX2 | chr17:61412242 C>T | 3'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs1240001061; called by muse, mutect2, varscan2
- WNK1 | c.2140-3047A>G | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs749154375, COSV100266615; called by muse, mutect2, varscan2
